Gene-level copy-number profile of tumor specimen TCGA-ZG-A9N3-01A from TCGA case TCGA-ZG-A9N3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.7 years (26,902 days).
Specimen TCGA-ZG-A9N3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a793c4a6-8339-411f-bea9-b04cb243e27d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZG-A9N3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/89ff621f-787f-459e-90ac-b6b7d21c2cab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,621; copy number 2: 22,534; copy number 3: 21,665; copy number 4: 11,271; copy number 5: 971; copy number 6: 686; copy number 7: 198; copy number 8: 227; copy number 9: 81; copy number 12: 443; copy number 13: 78; copy number 43: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZG-A9N3-01A-11D-A41J-01): tumor purity 0.56, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,945,502–87,994,695, 2 genes: RPL11P3, AC063965.1.
- chr16:68,530,090–68,576,072, 1 gene (within-gene range 0–1): ZFP90.
- chr16:68,573,782–68,835,541, 10 genes (within-gene range 0–1): AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,052 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:68,640,798–106,908,980, 719 genes, copy number 7–13 (broad region; genes not listed).
- chr8:84,665,759–101,492,499, 308 genes, copy number 8–9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:39,461,486–40,014,705, 25 genes, copy number 43: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3.

Autosomal genes at a single copy (total copy number 1): 1,621. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
